Somatic mutation profile of tumor specimen 28be2eb2-1c1c-4799-b5af-e4b447 (aliquot 28be2eb2-1c1c-4799-b5af-e4b447_D6_1) from CPTAC case 11BR053, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 61.5 years (22,477 days).
Specimen 28be2eb2-1c1c-4799-b5af-e4b447: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9abe40bb-58df-4ecf-888e-a67e3c64a109.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen a5ecd1b1-8075-4d46-9a4f-18b8b1 (Blood Derived Normal), aliquot a5ecd1b1-8075-4d46-9a4f-18b8b1_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a4ae82a3-f7c3-43b3-bfe4-0b1c612c7fce

The open-access MAF lists 75 somatic variants for this specimen: 54 protein-altering or splice-affecting, 16 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 16, Nonsense Mutation 4, 3'UTR 2, Splice Site 2, RNA 1, Intron 1, In Frame Del 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.380C>A p.S127Y | Missense Mutation (SNP) | VAF 91/124 reads (73%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52666031, COSV52675881, COSV52731113, COSV52828604; called by mutect2, varscan2
- ABCA4 | c.265G>C p.E89Q | Missense Mutation (SNP) | VAF 63/260 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as CM132927, COSV64676550; called by mutect2, varscan2
- ADAMTS10 | c.1195G>A p.G399S | Missense Mutation (SNP) | VAF 25/440 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs781912863; called by muse, mutect2
- ADAMTS3 | c.3388C>T p.R1130C | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as rs752528829; called by muse, mutect2, varscan2
- APOBR | c.1414G>A p.D472N (on ENST00000431282; = p.D481N on NM_018690.4) | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.105); catalogued as rs529411897; called by muse, mutect2, varscan2
- ASXL3 | c.6328G>A p.E2110K | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99324886; called by muse, mutect2, varscan2
- AUTS2 | c.3499C>T p.L1167F | Missense Mutation (SNP) | VAF 34/398 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1214271334; called by muse, mutect2
- CARMIL3 | c.1930G>A p.A644T | Missense Mutation (SNP) | VAF 54/486 reads (11%) | SIFT tolerated (0.88); PolyPhen benign (0.153); catalogued as rs142826860; called by muse, mutect2, varscan2
- CLCN7 | c.1155C>T p.G385= | Splice Region (SNP) | VAF 68/934 reads (7%) | catalogued as rs771365308; ClinVar: uncertain significance; called by muse, mutect2
- DNHD1 | c.8518C>T p.R2840* | Nonsense Mutation (SNP) | VAF 59/305 reads (19%) | catalogued as rs1342727634, COSV54439208; called by muse, mutect2, varscan2
- DRD4 | c.242T>C p.L81P | Missense Mutation (SNP) | VAF 81/444 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs759566156; called by muse, mutect2, varscan2
- EIF2AK3 | c.1532G>A p.R511H | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs1188393423, COSV100303644; called by muse, mutect2, varscan2
- IKZF5 | c.233T>C p.F78S | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.025); catalogued as rs767430220; called by muse, mutect2, varscan2
- LRRC61 | c.263C>T p.T88M | Missense Mutation (SNP) | VAF 98/815 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs139556045; called by muse, mutect2, varscan2
- MTMR11 | c.1909C>T p.R637C (on ENST00000439741 / NM_001145862.2; = p.R565C on NM_181873.3) | Missense Mutation (SNP) | VAF 17/257 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs371578546; called by muse, mutect2
- MUC4 | c.13654G>A p.E4552K (on ENST00000463781 / NM_018406.7; = p.E316K on NM_004532.6) | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.637); catalogued as COSV100207035; called by muse, mutect2, varscan2
- NLE1 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as rs145029268; called by muse, varscan2
- NUTM2B | c.325G>A p.G109R | Missense Mutation (SNP) | VAF 41/297 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.267); catalogued as rs748371075; called by muse, mutect2, varscan2
- PECAM1 | c.2192C>T p.T731M | Missense Mutation (SNP) | VAF 54/392 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.854); catalogued as rs782523890; called by muse, mutect2, varscan2
- RNF123 | c.3097G>A p.V1033I | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs199902925; called by muse, mutect2
- RPUSD3 | c.488G>T p.R163I | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs534495694; called by muse, mutect2, varscan2
- SETD1B | c.175-1G>A p.X59_splice | Splice Site (SNP) | VAF 12/62 reads (19%) | catalogued as COSV99930062; called by muse, mutect2, varscan2
- SH3TC2 | c.3722C>A p.A1241E | Missense Mutation (SNP) | VAF 36/508 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60466647; called by muse, mutect2
- SHROOM3 | c.5807G>A p.R1936Q | Missense Mutation (SNP) | VAF 58/283 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751522247, COSV56028049; called by muse, mutect2, varscan2
- TLX1 | c.212C>A p.A71E | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs992155351; called by muse, mutect2, varscan2
- TOGARAM1 | c.3095T>A p.L1032* | Nonsense Mutation (SNP) | VAF 10/84 reads (12%) | catalogued as COSV63892432; called by muse, mutect2, varscan2
- TTN | c.80042G>A p.R26681H (on ENST00000591111; = p.R19257H on NM_003319.4) | Missense Mutation (SNP) | VAF 63/200 reads (32%) | PolyPhen benign (0.017); catalogued as rs373532064; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- YWHAQ | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 53/271 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.739); catalogued as COSV53004340; called by muse, mutect2, varscan2
- ZMIZ2 | c.2093C>T p.P698L | Missense Mutation (SNP) | VAF 59/601 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.099); catalogued as rs981286302; called by muse, mutect2, varscan2
- AC090517.4 | c.1390_1392del p.C464del | In Frame Del (DEL) | VAF 6/13 reads (46%) | called by mutect2, varscan2
- ADCY2 | c.1489T>C p.Y497H | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- AP4M1 | c.116G>T p.G39V | Missense Mutation (SNP) | VAF 34/260 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ARHGAP35 | c.3068C>T p.S1023F | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- CFAP74 | c.4232T>C p.V1411A | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CLCN5 | c.79T>G p.S27A | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.89); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CNN1 | c.763C>T p.Q255* | Nonsense Mutation (SNP) | VAF 54/204 reads (26%) | called by muse, mutect2, varscan2
- CRB2 | c.2650G>A p.G884R | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- CRYBG3 | c.1765G>T p.A589S | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- EGF | c.1666G>A p.V556M | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- EPDR1 | c.270-2A>T p.X90_splice | Splice Site (SNP) | VAF 9/97 reads (9%) | called by muse, mutect2
- FGFR4 | c.1414C>T p.P472S | Missense Mutation (SNP) | VAF 41/218 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IGHV1-3 | c.140C>A p.T47N | Missense Mutation (SNP) | VAF 42/290 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- INTS7 | c.1594C>T p.Q532* | Nonsense Mutation (SNP) | VAF 5/34 reads (15%) | called by muse, mutect2
- MARCHF7 | c.803A>G p.Q268R | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- OSMR | c.1908G>T p.L636F | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- POLR2H | c.132C>G p.N44K | Missense Mutation (SNP) | VAF 5/108 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- POLR3B | c.2509C>A p.Q837K | Missense Mutation (SNP) | VAF 33/247 reads (13%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP1CC | c.895G>T p.A299S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, varscan2
- PRPF3 | c.805G>A p.G269S | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- RP1L1 | c.6115G>A p.G2039R | Missense Mutation (SNP) | VAF 96/131 reads (73%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.11); called by mutect2, varscan2
- TOGARAM1 | c.2322C>A p.S774R | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- WDR70 | c.1609C>A p.P537T | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- XKR5 | c.1601G>A p.G534E | Missense Mutation (SNP) | VAF 40/312 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ZMYND11 | c.950G>A p.R317K | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANK1 | c.2856C>A p.R952= | Silent (SNP) | VAF 129/1126 reads (11%) | called by muse, mutect2, varscan2
- ARMC5 | c.423G>A p.T141= | Silent (SNP) | VAF 144/415 reads (35%) | called by muse, mutect2, varscan2
- C1QL4 | c.189C>T p.R63= | Silent (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
- CAMSAP1 | c.4497C>T p.S1499= | Silent (SNP) | VAF 10/45 reads (22%) | called by muse, mutect2, varscan2
- GLT1D1 | c.673C>A p.R225= (on ENST00000442111 / NM_001366889.1; = p.R145= on NM_144669.3) | Silent (SNP) | VAF 5/61 reads (8%) | catalogued as COSV55880944; called by muse, mutect2
- LRP8 | c.543C>T p.A181= | Silent (SNP) | VAF 20/67 reads (30%) | called by muse, mutect2, varscan2
- NOL4L | c.252C>T p.A84= | Silent (SNP) | VAF 29/275 reads (11%) | catalogued as rs780855810; called by muse, mutect2, varscan2
- OVCH1 | c.2145C>A p.R715= | Silent (SNP) | VAF 21/54 reads (39%) | called by muse, mutect2, varscan2
- PPP2R2A | c.1137A>G p.L379= | Silent (SNP) | VAF 23/131 reads (18%) | catalogued as rs1327647767; called by muse, mutect2, varscan2
- SIPA1L1 | c.3246G>A p.P1082= | Silent (SNP) | VAF 36/258 reads (14%) | catalogued as rs780788529, COSV100665515; called by muse, mutect2, varscan2
- SPARC | c.498C>A p.R166= | Silent (SNP) | VAF 44/420 reads (10%) | called by muse, mutect2, varscan2
- SRC | c.1236G>T p.R412= | Silent (SNP) | VAF 9/111 reads (8%) | called by muse, mutect2
- SRRM2 | c.1917A>G p.S639= | Silent (SNP) | VAF 68/928 reads (7%) | called by muse, mutect2
- TM9SF1 | c.1566C>T p.F522= | Silent (SNP) | VAF 71/211 reads (34%) | called by muse, mutect2, varscan2
- ZNF202 | c.747C>T p.D249= | Silent (SNP) | VAF 6/38 reads (16%) | called by mutect2, varscan2
- ZNF711 | c.828A>T p.V276= | Silent (SNP) | VAF 21/128 reads (16%) | called by muse, mutect2
- DNASE1L1 | chrX:154412017 G>T | 5'Flank (SNP) | VAF 22/482 reads (5%) | called by muse, mutect2
- FAM227A | c.*3214G>A | 3'UTR (SNP) | VAF 9/39 reads (23%) | catalogued as rs1264177532, COSV100874659; called by muse, mutect2, varscan2
- IGF2BP2 | c.240-23930T>C | Intron (SNP) | VAF 6/69 reads (9%) | called by muse, mutect2
- LINC02610 | n.2888C>T | RNA (SNP) | VAF 31/225 reads (14%) | catalogued as rs1189690507; called by muse, mutect2, varscan2
- RFX5 | c.*35C>T | 3'UTR (SNP) | VAF 74/326 reads (23%) | catalogued as rs550837956, COSV51840114; called by muse, mutect2, varscan2
